Somatic mutation profile of tumor specimen ALCH-ADWB-TTP1-A (aliquot ALCH-ADWB-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADWB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 53.2 years (19,430 days).
Specimen ALCH-ADWB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d242112-b305-49b3-b17d-e300dd87aa2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADWB-NB1-A (Blood Derived Normal), aliquot ALCH-ADWB-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85b61557-b75c-4233-b654-0af57fd2c5d4

The open-access MAF lists 160 somatic variants for this specimen: 102 protein-altering or splice-affecting, 43 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 43, Nonsense Mutation 7, Intron 7, Splice Site 3, 5'Flank 3, 3'UTR 2, RNA 2, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4516C>G p.R1506G | Missense Mutation (SNP) | VAF 41/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99683967; called by muse, mutect2
- ALMS1 | c.2524G>T p.G842* | Nonsense Mutation (SNP) | VAF 16/330 reads (5%) | catalogued as rs1258140663; called by muse, mutect2
- ANKRD1 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 36/621 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.821); catalogued as COSV63311134; called by muse, mutect2
- ARMH4 | c.2152G>T p.V718L | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50772104; called by muse, mutect2
- CAPS2 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761523502; called by mutect2, varscan2
- CLVS1 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV57970316; called by muse, mutect2
- COL4A5 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM151518; called by muse, mutect2
- CSMD3 | c.2957C>A p.T986K (on ENST00000297405 / NM_001363185.1; = p.T882K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV52307615; called by muse, mutect2
- CSMD3 | c.1271G>C p.S424T | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV52254000; called by muse, mutect2
- DAB1 | c.1558C>A p.P520T (on ENST00000371231; = p.P487T on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64694264, COSV64696184; called by muse, mutect2
- DACH2 | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100913186; called by muse, mutect2
- ESR1 | c.1664G>T p.R555L | Missense Mutation (SNP) | VAF 57/627 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as CM1212985, COSV52786790; called by muse, mutect2
- FAM3D | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs1443449054, COSV100716770; called by muse, mutect2
- GPR119 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs763262224, COSV99358747; called by muse, mutect2, varscan2
- IGHD | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV66655517; called by muse, mutect2
- KEL | c.1339C>G p.R447G | Missense Mutation (SNP) | VAF 33/608 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as CM165854; called by muse, mutect2
- KRT27 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV56972781; called by muse, mutect2
- LPA | c.4663G>T p.D1555Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60304929; called by muse, mutect2
- NACA2 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104437375; called by muse, mutect2
- PCDHGA3 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1383007009; called by muse, mutect2
- PGBD2 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 34/558 reads (6%) | catalogued as COSV100252314; called by muse, mutect2
- PHLDB3 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1237811443; called by muse, mutect2
- PP2D1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1188473620; called by muse, mutect2
- PRX | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs537664679, COSV99398162; ClinVar: uncertain significance; called by muse, mutect2
- RASSF2 | c.672C>A p.Y224* | Nonsense Mutation (SNP) | VAF 34/554 reads (6%) | catalogued as COSV65082395; called by muse, mutect2
- RFPL4AL1 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 63/2220 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV59113097; called by muse, mutect2
- SRSF6 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.268); catalogued as COSV54828323; called by muse, mutect2
- SYNE1 | c.12373G>A p.A4125T (on ENST00000367255 / NM_182961.4; = p.A4054T on NM_033071.3) | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs1313423194; called by muse, mutect2
- TBC1D4 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 23/335 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs567936519, COSV100884774; called by muse, mutect2
- USP29 | c.2656G>T p.G886W | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV54146677; called by muse, mutect2
- ZNF135 | c.1328G>A p.C443Y (on ENST00000313434 / NM_001289401.2; = p.C455Y on NM_003436.4) | Missense Mutation (SNP) | VAF 43/499 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763586466; called by muse, mutect2
- ZYX | c.937A>C p.S313R | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV59557328; called by muse, mutect2
- A1CF | c.1175G>C p.G392A (on ENST00000373993 / NM_138932.2; = p.G384A on NM_014576.4) | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ALMS1 | c.2525G>T p.G842V | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANK1 | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 16/533 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- APOBEC1 | c.499T>G p.W167G | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP35 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- ARID2 | c.2950G>T p.V984F | Missense Mutation (SNP) | VAF 19/329 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); called by muse, mutect2
- CACNA1C | c.3585G>T p.K1195N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CACNA1I | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- CD33 | c.873del p.T292Qfs*57 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, varscan2
- CNGB3 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 46/486 reads (9%) | called by muse, mutect2
- CRISPLD1 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); called by muse, mutect2
- CSDE1 | c.1706G>T p.G569V (on ENST00000358528 / NM_001007553.3; = p.G538V on NM_007158.6) | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.6395C>A p.P2132H (on ENST00000297405 / NM_001363185.1; = p.P2028H on NM_052900.3) | Missense Mutation (SNP) | VAF 48/710 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2
- CTNND2 | c.2597C>A p.A866E | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTSA | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- CTSK | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 36/656 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DISC1 | c.1731A>T p.K577N | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2
- DPYS | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- EVC2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- EXT2 | c.1077G>T p.K359N (on ENST00000343631; = p.K392N on NM_000401.3) | Missense Mutation (SNP) | VAF 45/824 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); called by muse, mutect2
- FMN2 | c.2234A>T p.Q745L | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- FSHR | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 46/632 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GIMAP7 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GJB7 | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- HECW1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPUL2 | c.751+3A>T | Splice Region (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- IL17F | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 23/630 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, mutect2
- IPO5 | c.866C>G p.T289S | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.109); called by muse, mutect2
- KIAA1549L | c.4697C>A p.S1566Y (on ENST00000321505; = p.S1863Y on NM_012194.3) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA1 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 15/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LILRB2 | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2
- LMX1A | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 39/613 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- LPAR3 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPXN | c.14-1G>C p.X5_splice | Splice Site (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- MANEA | c.1240G>C p.A414P | Missense Mutation (SNP) | VAF 41/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRC1 | c.2386+2T>C p.X796_splice | Splice Site (SNP) | VAF 18/586 reads (3%) | called by muse, mutect2
- MRC1 | c.3217A>C p.S1073R | Missense Mutation (SNP) | VAF 44/781 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2
- MTM1 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- MTR | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYOM1 | c.3766G>T p.E1256* | Nonsense Mutation (SNP) | VAF 13/231 reads (6%) | called by muse, mutect2
- NLRP8 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NOBOX | c.1524C>A p.Y508* | Nonsense Mutation (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- NRIP2 | c.800T>G p.F267C | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- OPN1LW | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.805); called by muse, mutect2
- OR2F2 | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- OR52N5 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIKFYVE | c.4398G>C p.E1466D | Missense Mutation (SNP) | VAF 22/734 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- PRKAB2 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- PRKRA | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 40/1504 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RYR2 | c.11091G>T p.K3697N | Missense Mutation (SNP) | VAF 18/507 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- RYR2 | c.11091+1G>T p.X3697_splice | Splice Site (SNP) | VAF 20/504 reads (4%) | called by muse, mutect2
- RYR2 | c.12421A>T p.S4141C | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- RYR3 | c.5026G>C p.G1676R | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2
- SCN2A | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 39/479 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- SLC14A2 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- SLC4A3 | c.2206G>C p.G736R | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SMC3 | c.2896T>A p.F966I | Missense Mutation (SNP) | VAF 29/568 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2
- SPATA31D1 | c.2569G>T p.V857F | Missense Mutation (SNP) | VAF 30/770 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SPTBN2 | c.2845G>T p.G949C | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- SUMF1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- SV2A | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2
- TMEM255A | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- TPP2 | c.1737G>T p.W579C | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM56 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- UBE2NL | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UGT3A1 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- USP34 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2
- VWC2L | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ZNF385D | c.603A>T p.K201N | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ZNF605 | c.674A>T p.H225L | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA12 | c.5830C>T p.L1944= (on ENST00000272895 / NM_173076.3; = p.L1626= on NM_015657.3) | Silent (SNP) | VAF 20/616 reads (3%) | catalogued as COSV55956899; called by muse, mutect2
- ADGB | c.4734C>A p.T1578= | Silent (SNP) | VAF 28/486 reads (6%) | called by muse, mutect2
- ANK1 | c.906C>A p.T302= | Silent (SNP) | VAF 16/534 reads (3%) | called by muse, mutect2
- CBLN4 | c.180G>T p.L60= | Silent (SNP) | VAF 18/247 reads (7%) | called by muse, mutect2
- CCDC185 | c.804G>A p.K268= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV64820632; called by muse, mutect2
- DCLK2 | c.2139T>C p.P713= | Silent (SNP) | VAF 14/333 reads (4%) | catalogued as rs1385969943; called by muse, mutect2
- DVL3 | c.759C>T p.N253= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- DYNC2LI1 | c.180A>T p.P60= | Silent (SNP) | VAF 16/221 reads (7%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1711C>A p.R571= | Silent (SNP) | VAF 17/261 reads (7%) | catalogued as COSV62570319; called by muse, mutect2
- EYA1 | c.165G>C p.T55= | Silent (SNP) | VAF 48/886 reads (5%) | catalogued as COSV100378754; called by muse, mutect2
- FAM135B | c.1005C>A p.L335= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as COSV52750853; called by muse, mutect2, varscan2
- FAT1 | c.4407A>G p.T1469= | Silent (SNP) | VAF 20/637 reads (3%) | called by muse, mutect2
- FAT3 | c.9672C>T p.I3224= | Silent (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- FCRL5 | c.1542G>T p.L514= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- GBP5 | c.813C>A p.I271= | Silent (SNP) | VAF 23/501 reads (5%) | called by muse, mutect2
- GRM3 | c.1047C>A p.P349= | Silent (SNP) | VAF 30/401 reads (7%) | called by muse, mutect2
- HEATR5B | c.3690G>T p.T1230= | Silent (SNP) | VAF 30/516 reads (6%) | called by muse, mutect2
- ITM2C | c.567G>T p.G189= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- KCNU1 | c.2454C>A p.I818= | Silent (SNP) | VAF 26/413 reads (6%) | called by muse, mutect2
- KCNU1 | c.2619T>C p.F873= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as rs1180393369, COSV67759956; called by mutect2, varscan2
- KIF3C | c.420G>T p.L140= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- KLK6 | c.342C>A p.R114= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- LRP1B | c.8169C>T p.N2723= | Silent (SNP) | VAF 25/234 reads (11%) | called by muse, varscan2
- MINAR2 | c.102G>C p.L34= | Silent (SNP) | VAF 27/491 reads (5%) | called by muse, mutect2
- NOS2 | c.1662C>T p.A554= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- NRXN2 | c.2628C>T p.S876= | Silent (SNP) | VAF 16/211 reads (8%) | called by muse, mutect2
- OR2M5 | c.405C>A p.L135= | Silent (SNP) | VAF 30/452 reads (7%) | called by muse, mutect2
- PLTP | c.915C>A p.A305= | Silent (SNP) | VAF 17/340 reads (5%) | called by muse, mutect2
- PRR32 | c.162G>C p.P54= | Silent (SNP) | VAF 36/514 reads (7%) | catalogued as COSV64420606; called by muse, mutect2
- PRSS55 | c.822G>A p.L274= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- RBM4 | c.288C>T p.A96= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- REG3G | c.60C>A p.L20= | Silent (SNP) | VAF 31/398 reads (8%) | catalogued as rs747199182; called by muse, mutect2
- RELN | c.2202C>G p.V734= | Silent (SNP) | VAF 60/1121 reads (5%) | called by muse, mutect2
- SF3B3 | c.834G>T p.L278= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- SLC7A3 | c.1050G>A p.L350= | Silent (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- SLITRK4 | c.1152C>A p.V384= | Silent (SNP) | VAF 45/521 reads (9%) | called by muse, mutect2
- SOWAHB | c.405T>A p.G135= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- TAF7L | c.969G>A p.E323= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- TBX20 | c.240G>T p.L80= | Silent (SNP) | VAF 15/305 reads (5%) | called by muse, mutect2
- TM7SF2 | c.192G>T p.L64= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1671C>A p.P557= | Silent (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- Z83844.2 | c.1734C>T p.A578= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- ZFYVE26 | c.5049G>A p.E1683= | Silent (SNP) | VAF 23/316 reads (7%) | called by muse, mutect2
- ABCA4 | c.-45A>G | 5'UTR (SNP) | VAF 24/532 reads (5%) | called by muse, mutect2
- ADAM6 | n.1431C>T | RNA (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- ARHGEF4 | chr2:130916603 G>T | 5'Flank (SNP) | VAF 11/148 reads (7%) | catalogued as rs1325591492; called by muse, mutect2
- ATP5MC1 | c.39+36G>T | Intron (SNP) | VAF 22/324 reads (7%) | called by muse, mutect2
- C1QTNF1 | c.-14-153C>T | Intron (SNP) | VAF 38/546 reads (7%) | called by muse, mutect2
- ERVV-1 | chr19:53010373 C>A | 5'Flank (SNP) | VAF 23/279 reads (8%) | called by muse, mutect2
- FRMD8P1 | n.346G>T | RNA (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- GRIK5 | c.2514+1043C>G | Intron (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- GRIK5 | c.2514+1041C>T | Intron (SNP) | VAF 11/251 reads (4%) | called by muse, mutect2
- HBE1 | c.-267+102532G>T | Intron (SNP) | VAF 30/495 reads (6%) | called by muse, mutect2
- IPO9 | c.*109C>T | 3'UTR (SNP) | VAF 13/162 reads (8%) | called by muse, mutect2
- KMT2E | c.3469-361A>T | Intron (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- LIPT2 | chr11:74497670 G>T | 5'Flank (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- NR1I2 | c.-23+492G>T | Intron (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
- XIAP | c.*2145C>A | 3'UTR (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
